CCDI case PBCLRF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/e468b3fb-1750-4ed8-b73f-c2cd394044ff

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 4.0 years (1,462 days).

Biospecimens (3 samples)
- Sample 0DUVT2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUVTB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUVUN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
